Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A264, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A264-06A (Metastatic).

[page 1 of 2]
ICD-0-3

Melanoma, malignant, NOS 8720/3

Site: Groin, NOS C44.5 fu 4/27/11

SPECIMENS:

- A. CONTENTS LT SUPERFICIAL GROIN
- B. LT INTERNAL ILIAC & OBTURATOR LNS
- C. EXCESS SKIN LEFT GROIN

DIAGNOSIS:

SKIN AND SUBCUTANEOUS TISSUE, LEFT SUPERFICIAL GROIN CONTENTS, EXCISION:

- METASTATIC MELANOMA, SEE COMMENT.
- 4.5 CM IN GREATEST DIMENSION.
- 4.0 X 3.5 CM IN ADDITIONAL DIMENSIONS.
- FOCALLY POSITIVE DEEP MARGIN (SLIDE A6).

LYMPH NODES, LEFT INTERNAL ILIAC AND OBTURATOR, EXCISION:

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES (0/4).

SKIN, LEFT GROIN, EXCISION:

- NO MALIGNANCY IDENTIFIED.

SPECIMEN(S):

A. CONTENTS LT SUPERFICIAL GROIN B. LT INTERNAL ILIAC & OBTURATOR LNS C. EXCESS SKIN LEFT GROIN

GROSS DESCRIPTION:

A. CONTENTS LEFT SUPERFICIAL GROIN

Received fresh for tumor procurement and labeled "contents left superficial groin" is an ellipse of soft tissue with skin measuring 28 x 9 x 5.8 cm. The skin is 25 x 1.5 cm. There are two sutures attached to the specimen orienting distal saphenous (long double silk) and proximal sphenoid (long single). The specimen is inked as follows: distal saphenous area inked orange, superior-red, medial-blue, lateral-yellow, posterior deep margin-black. There is a tumor mass present centrally in the subcutaneous tissue, measuring 4.5 x 4.0 x 3.5 cm. Sections reveal a gray-tan, solid, nodular mass. The deep margin is grossly positive for tumor. One cm from the main mass is another small nodule measuring 0.7 cm in greatest dimension. This mass is solid, gray-white and well circumscribed. Two cm away from the main mass is a third mass measuring 1.2 x 1.0 x 1.0 cm. This mass is well-circumscribed, gray-white and solid. The third mass is 1.0 cm from the posterior resection margin. The saphenous vein is probe-patent. The rest of the tissue is fatty and unremarkable. The skin is not involved.. Representative sections are submitted in 14 cassettes.

Summary of sections:

A1-A8: a central full section of the tumor including anterior, deep, lateral, medial and deep margin

A9: the major mass with 2nd small nodule and saphenous vein

A10: the major mass with the relation of the saphenous vein

A11: the 3rd nodule with posterior margin

A12-A13: superior tip

A14: inferior tip

B. LEFT INTERNAL ILIAC AND OBTURATOR LYMPH NODES

Received fresh and labeled "left internal iliac and obturator lymph nodes" are 2 fragments of fatty adipose tissue aggregating 3.0 x 2.0 x 1.0 cm. Serial dissections reveal multiple lymph nodes ranging from 0.5 cm in greatest dimension to 2.2 x 1.0 x 0.5 cm. Lymph nodes are entirely submitted in 4 cassettes.

B1: bisected lymph nodes

B2: multiple lymph nodes

B3: 1 large lymph node

B4: the remaining fibrous tissue

C. EXCESS SKIN LEFT GROIN

Received fresh and labeled "excess skin left groin" is a long strip of the skin measuring 62 x 2 x 1 cm. Serial sections are unremarkable. Representative sections are submitted in 3 cassettes.

[page 2 of 2]
COMMENT:

Multiple nodules of tumor are identified in the contents of the left superficial groin (part A), which likely represent completely replaced matted lymph nodes. Four additional lymph nodes are negative for melanoma from this part. This case was compared to the previous case (), and the tumors are similar.

Pathologist
Electronically signed

ADDENDUM: AS DESCRIBED ABOVE, IT IS DIFFICULT TO DETERMINE THE NUMBER OF LYMPH NODES INVOLVED BY TUMOR SINCE THE NODES ARE COMPLETELY REPLACED BY TUMOR AND MATTED. HOWEVER, UPON THE REQUEST OF THE CLINICIAN, AN ESTIMATE TO THE NUMBER OF INVOLVED LYMPH NODES IS TWELVE OF TWENTY (12/20). THE DEEP MARGIN IS ONLY MICROSCOPICALLY INVOLVED BY TUMOR OVER A LENGTH OF <0.1 CM.

Gross Dictation:., Pathology Fellow,
Microscopic/Diagnostic Dictation:., Pathologist,
Microscopic/Diagnostic Dictation: Pathologist,
Final Review: Pathologist.
Final: Pathologist,
Addendum:., Pathologist,
Addendum Final: Pathologist,

SLPAA Discrepancy		/

Source: NCI Genomic Data Commons file f5ef2317-1972-47d5-8ddc-8badcf9473f2 (TCGA-GN-A264.4C110E59-4624-4A8E-9B5C-C348FA62420A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).